Gene-level copy-number profile of tumor specimen TCGA-BR-8297-01A from TCGA case TCGA-BR-8297, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 58.1 years (21,224 days).
Specimen TCGA-BR-8297-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4079964f-66f4-49bf-8f3a-bbf4ea4c7af5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8297-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7af17804-558c-4ee2-93df-09d312117145

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,728; copy number 2: 38,363; copy number 3: 13,733; copy number 4: 2,053; copy number 5: 1,692; copy number 6: 17; copy number 7: 44; copy number 8: 5; copy number 11: 49; copy number 13: 34; copy number 18: 23; copy number 19: 28; copy number 21: 13; copy number 29: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8297-01A-12D-2338-01): tumor purity 0.22, ploidy 4.41, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:27,335,968–27,595,164, 1 gene (within-gene range 0–2): AC090403.1.
- chr18:27,418,884–29,048,719, 11 genes: RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,921 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–75,183,048, 156 genes, copy number 5 (broad region; genes not listed).
- chr8:49,086,301–145,066,685, 1,471 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:34,570,876–36,232,136, 29 genes, copy number 21–29 (within-gene range 2–29): LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973.
- chr11:119,709,920–120,489,937, 17 genes, copy number 6 (within-gene range 2–6): NECTIN1-AS1, AP003390.1, AP001994.1, AP001994.2, AP001994.3, AP001360.3, LINC02744, AP001360.1, AP001360.2, TRIM29, AP000679.1, OAF, POU2F3, AP001150.1, TLCD5, ARHGEF12, 7SK.
- chr12:24,704,503–25,648,579, 25 genes, copy number 11–18 (within-gene range 2–18): AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr18:7,995,570–8,155,070, 4 genes, copy number 8: U3, AP005900.1, AC006566.2, AC006566.1.
- chr18:8,609,437–9,648,502, 30 genes, copy number 5: RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856.
- chr18:11,366,913–13,764,556, 91 genes, copy number 7–11 (broad region; genes not listed).
- chr18:20,946,906–25,352,190, 98 genes, copy number 5–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,188. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
